Somatic mutation profile of tumor specimen MBCProject_1667_T1_WES (aliquot MBCProject_1667_T1_WES_1) from CMI case MBCProject_1667, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 39.0 years (14,251 days).
Specimen MBCProject_1667_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Omentum; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 797814fe-b901-4042-a202-76b6b64fd65a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1667_SALIVA (Saliva), aliquot MBCProject_1667_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b82bc41-53b6-4b4d-85d9-ffdd9815cb0a

The open-access MAF lists 148 somatic variants for this specimen: 89 protein-altering or splice-affecting, 36 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 36, Nonsense Mutation 8, RNA 7, Intron 7, Splice Region 4, 5'Flank 4, 5'UTR 3, Frame Shift Del 3, 3'Flank 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF2 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.216); catalogued as rs376806668; called by muse, mutect2, varscan2
- AFF3 | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57877597; called by muse, mutect2, varscan2
- AHNAK | c.11132A>G p.K3711R | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as rs778445642; called by muse, mutect2, varscan2
- AKT1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.515); catalogued as COSV62573390; called by muse, mutect2, varscan2
- ALPK2 | c.1825G>C p.E609Q | Missense Mutation (SNP) | VAF 23/259 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as COSV64491083; called by muse, mutect2
- ARHGAP35 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 53/232 reads (23%) | catalogued as COSV101350595; called by muse, mutect2, varscan2
- ATF1 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs781338514; called by muse, mutect2, varscan2
- C9orf131 | c.2266G>A p.G756R | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs781037031; called by muse, mutect2, varscan2
- CHMP2B | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs764069353; called by muse, mutect2, varscan2
- CRACD | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs977713314; called by muse, mutect2, varscan2
- CTSA | c.1028A>G p.N343S | Missense Mutation (SNP) | VAF 50/594 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1396788895; called by muse, mutect2
- CUEDC1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs957586221, COSV100804634, COSV64227368; called by muse, mutect2, varscan2
- DHX30 | c.3403G>A p.V1135M (on ENST00000445061 / NM_138615.3; = p.V1096M on NM_014966.3) | Missense Mutation (SNP) | VAF 63/297 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs753692624, COSV99274638; called by muse, mutect2, varscan2
- EGF | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 108/452 reads (24%) | catalogued as rs772589488; called by muse, mutect2, varscan2
- ERBB4 | c.2851A>C p.M951L | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV61497795; called by muse, mutect2, varscan2
- FBXO33 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 257/1024 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as rs1489916624; called by muse, mutect2, varscan2
- GJA5 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 84/332 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV54786255; called by muse, mutect2, varscan2
- GPR50 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs779386501, COSV54437246; called by muse, mutect2, varscan2
- GRXCR1 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV67670223; called by muse, mutect2, varscan2
- HIBCH | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 101/699 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.075); catalogued as rs557894738; called by muse, mutect2, varscan2
- KCNA2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV60368676; called by muse, mutect2, varscan2
- KIAA0100 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 50/365 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV101197227; called by muse, mutect2, varscan2
- LAD1 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as rs571739831; called by muse, mutect2, varscan2
- LRRC10B | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.09); catalogued as rs542936613; called by muse, mutect2, varscan2
- MCM7 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 169/701 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as rs1360767264; called by muse, mutect2, varscan2
- MMP11 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 43/285 reads (15%) | catalogued as rs1267449886, COSV99303480; called by muse, mutect2, varscan2
- NLK | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV69410030; called by muse, varscan2
- NLRP14 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as COSV100205244; called by muse, mutect2, varscan2
- NXPH2 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.42); catalogued as COSV55642953; called by muse, varscan2
- OR4K17 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59648646; called by muse, mutect2, varscan2
- PAK6 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.563); catalogued as COSV53046040; called by muse, mutect2, varscan2
- PLD6 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as COSV58634475; called by muse, mutect2, varscan2
- PPP1R37 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as rs1047994528, COSV99541728; called by muse, mutect2, varscan2
- PRR23B | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as COSV61493128; called by muse, mutect2, varscan2
- PRR36 | c.2014C>T p.L672F | Missense Mutation (SNP) | VAF 71/305 reads (23%) | SIFT deleterious, low confidence (0.05); catalogued as rs1326419659; called by muse, mutect2, varscan2
- PRRG4 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767092665; called by muse, mutect2, varscan2
- SEMA3G | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs140387468; called by muse, mutect2, varscan2
- SEPTIN4 | c.452-3C>T | Splice Region (SNP) | VAF 34/126 reads (27%) | catalogued as rs770761656; called by muse, mutect2, varscan2
- SERPINB8 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 49/366 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV54639422; called by muse, mutect2, varscan2
- SLC28A1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 48/365 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs375692167; called by muse, mutect2, varscan2
- SMARCD2 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs781146536, COSV99856334; called by muse, mutect2, varscan2
- STAG2 | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54367633, COSV54369674; called by muse, mutect2, varscan2
- SYT10 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750127932, COSV57346761; called by muse, mutect2, varscan2
- TAS1R3 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.48); catalogued as rs569364281; called by muse, mutect2, varscan2
- TCF15 | c.316C>A p.R106S | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1365608842; called by muse, mutect2, varscan2
- TRIM36 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767008678, COSV56691797; called by muse, mutect2, varscan2
- ZNF662 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.757); catalogued as rs200357760; called by muse, mutect2, varscan2
- ANKRD36C | c.4876C>T p.Q1626* | Nonsense Mutation (SNP) | VAF 39/223 reads (17%) | called by muse, mutect2, varscan2
- CAPS2 | c.898A>G p.R300G | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD101 | c.42G>A p.L14= | Splice Region (SNP) | VAF 30/132 reads (23%) | called by muse, mutect2, varscan2
- CD84 | c.812-7G>A | Splice Region (SNP) | VAF 57/287 reads (20%) | called by muse, mutect2, varscan2
- CDH24 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2
- CHD7 | c.950A>G p.N317S | Missense Mutation (SNP) | VAF 76/733 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- CUL5 | c.2013G>C p.E671D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, varscan2
- FAR1 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- GCG | c.116A>G p.D39G | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- GNPDA2 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 32/137 reads (23%) | called by muse, mutect2, varscan2
- H2AC6 | c.268A>G p.N90D | Missense Mutation (SNP) | VAF 128/788 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- HIVEP1 | c.2918A>G p.N973S | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRF7 | c.656T>G p.V219G (on ENST00000397566; = p.V206G on NM_001572.5) | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ISL1 | c.723C>G p.I241M | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- KMT2C | c.10984G>T p.E3662* | Nonsense Mutation (SNP) | VAF 66/263 reads (25%) | called by muse, mutect2, varscan2
- LRR1 | c.1235_1239del p.M412Kfs*44 | Frame Shift Del (DEL) | VAF 24/81 reads (30%) | called by mutect2, pindel, varscan2
- MAP2 | c.5065G>A p.G1689R | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MAP3K1 | c.929_930del p.K310Sfs*15 | Frame Shift Del (DEL) | VAF 157/801 reads (20%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.1239_1240dup p.R414Hfs*23 | Frame Shift Ins (INS) | VAF 69/356 reads (19%) | called by mutect2, pindel, varscan2
- MEGF8 | c.7644T>A p.D2548E (on ENST00000251268 / NM_001271938.2; = p.D2481E on NM_001410.3) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- NEUROD1 | c.851C>G p.S284C | Missense Mutation (SNP) | VAF 261/995 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NFKBIB | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2, varscan2
- NKAPL | c.681G>C p.K227N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PARP1 | c.1160-1G>A p.X387_splice | Splice Site (SNP) | VAF 96/563 reads (17%) | called by muse, mutect2, varscan2
- PLA2G6 | c.798-8C>T | Splice Region (SNP) | VAF 28/233 reads (12%) | called by muse, mutect2, varscan2
- PPP1R13B | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTHLH | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 106/354 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RAB3GAP1 | c.2228C>G p.A743G | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- RAVER2 | c.1493G>A p.G498E (on ENST00000294428 / NM_001366165.1; = p.G485E on NM_018211.4) | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- RORB | c.549G>A p.M183I (on ENST00000396204 / NM_001365023.1; = p.M172I on NM_006914.4) | Missense Mutation (SNP) | VAF 38/381 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RPL9 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, varscan2
- SLC40A1 | c.567del p.M190Wfs*7 | Frame Shift Del (DEL) | VAF 58/404 reads (14%) | called by mutect2, pindel, varscan2
- SOCS5 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TAF1 | c.1771A>G p.K591E (on ENST00000373790 / NM_138923.4; = p.K612E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, varscan2
- TDRD9 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM190 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- TRAM1 | c.669_674del p.V224_L225del | In Frame Del (DEL) | VAF 8/83 reads (10%) | called by mutect2, pindel
- TRRAP | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2
- TTN | c.65071G>C p.D21691H (on ENST00000591111; = p.D14267H on NM_003319.4) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TWIST1 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 104/682 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.491); called by muse, varscan2
- UBXN7 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZMYM2 | c.2731C>T p.P911S | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABCC9 | c.2157C>T p.L719= | Silent (SNP) | VAF 23/244 reads (9%) | catalogued as rs201848437, COSV53973502; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP21 | c.3192G>C p.L1064= | Silent (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- C8orf34 | c.1616G>A p.*539= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as rs267601979, COSV61380849, COSV61399218; called by muse, mutect2, varscan2
- CCDC149 | c.621G>A p.E207= | Silent (SNP) | VAF 46/269 reads (17%) | called by muse, mutect2, varscan2
- CCNF | c.1122C>T p.I374= | Silent (SNP) | VAF 35/144 reads (24%) | called by muse, mutect2, varscan2
- CDC42EP1 | c.414C>T p.L138= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV50758239; called by muse, mutect2, varscan2
- DRAXIN | c.915C>T p.F305= | Silent (SNP) | VAF 31/241 reads (13%) | catalogued as rs753503038, COSV53842216; called by muse, mutect2, varscan2
- DUSP26 | c.276C>G p.L92= | Silent (SNP) | VAF 69/244 reads (28%) | called by muse, mutect2, varscan2
- ERICH3 | c.4467G>A p.E1489= | Silent (SNP) | VAF 55/288 reads (19%) | catalogued as COSV58612662; called by muse, mutect2, varscan2
- FRMPD4 | c.2181C>T p.A727= | Silent (SNP) | VAF 60/445 reads (13%) | catalogued as rs752460391, COSV66222341; called by muse, mutect2, varscan2
- GADD45G | c.417C>T p.S139= | Silent (SNP) | VAF 62/264 reads (23%) | called by muse, mutect2, varscan2
- GPR68 | c.795C>T p.F265= | Silent (SNP) | VAF 22/202 reads (11%) | catalogued as COSV53176767, COSV99032164; called by muse, mutect2
- HACD3 | c.99C>T p.I33= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- MIA3 | c.663G>A p.Q221= | Silent (SNP) | VAF 101/314 reads (32%) | called by muse, mutect2, varscan2
- MINK1 | c.39C>T p.I13= | Silent (SNP) | VAF 49/181 reads (27%) | called by muse, mutect2, varscan2
- MRPL2 | c.37C>T p.L13= | Silent (SNP) | VAF 42/160 reads (26%) | catalogued as rs34378482; called by muse, varscan2
- MUC16 | c.29298G>A p.V9766= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs952601642; called by muse, mutect2, varscan2
- NDUFAF1 | c.456G>A p.L152= | Silent (SNP) | VAF 76/313 reads (24%) | called by muse, mutect2, varscan2
- NXPH2 | c.198C>A p.P66= | Silent (SNP) | VAF 24/224 reads (11%) | called by muse, varscan2
- OR8U1 | c.621C>T p.F207= | Silent (SNP) | VAF 20/186 reads (11%) | catalogued as rs764876652, COSV56418928; called by muse, varscan2
- PKD1 | c.756G>A p.P252= | Silent (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- RD3L | c.174T>C p.G58= | Silent (SNP) | VAF 41/301 reads (14%) | catalogued as rs563244510; called by muse, mutect2, varscan2
- RELN | c.4002G>A p.V1334= | Silent (SNP) | VAF 40/337 reads (12%) | called by muse, mutect2, varscan2
- RGS8 | c.489G>A p.L163= (on ENST00000367556 / NM_001369564.2; = p.L181= on NM_033345.3) | Silent (SNP) | VAF 105/306 reads (34%) | called by muse, mutect2, varscan2
- RLBP1 | c.483C>T p.F161= | Silent (SNP) | VAF 36/329 reads (11%) | called by muse, mutect2, varscan2
- RPS15 | c.66C>G p.L22= | Silent (SNP) | VAF 93/360 reads (26%) | catalogued as rs769722014; called by muse, mutect2, varscan2
- SDCCAG8 | c.1536G>A p.Q512= | Silent (SNP) | VAF 76/442 reads (17%) | catalogued as COSV100654473; called by muse, mutect2, varscan2
- SNAPC1 | c.45C>T p.L15= | Silent (SNP) | VAF 150/603 reads (25%) | catalogued as rs1313591237; called by muse, mutect2, varscan2
- SYTL3 | c.312G>A p.T104= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs758303337; called by muse, mutect2, varscan2
- TBC1D22B | c.33G>A p.K11= | Silent (SNP) | VAF 70/286 reads (24%) | catalogued as COSV60825377; called by muse, mutect2, varscan2
- TBX2 | c.1233C>T p.S411= | Silent (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- TGFB1I1 | c.618C>G p.T206= (on ENST00000394863 / NM_001042454.3; = p.T189= on NM_015927.4) | Silent (SNP) | VAF 32/273 reads (12%) | called by muse, mutect2, varscan2
- UNC5A | c.741G>A p.P247= | Silent (SNP) | VAF 20/190 reads (11%) | catalogued as rs574597045; called by muse, mutect2, varscan2
- USP34 | c.2853G>A p.L951= | Silent (SNP) | VAF 27/128 reads (21%) | called by muse, mutect2, varscan2
- UTP14A | c.81C>G p.L27= | Silent (SNP) | VAF 13/194 reads (7%) | called by muse, mutect2
- ZNF696 | c.660G>A p.Q220= | Silent (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- AC104472.1 | n.449A>T | RNA (SNP) | VAF 38/168 reads (23%) | called by muse, mutect2, varscan2
- ACAT2 | chr6:159761534 C>T | 5'Flank (SNP) | VAF 78/364 reads (21%) | called by muse, mutect2, varscan2
- BRD1 | c.2360-108C>T | Intron (SNP) | VAF 60/261 reads (23%) | called by muse, mutect2, varscan2
- CDKL1 | chr14:50395907 G>A | 5'Flank (SNP) | VAF 30/115 reads (26%) | catalogued as rs367656406; called by muse, mutect2, varscan2
- CEP295 | chr11:93732116 A>C | 3'Flank (SNP) | VAF 10/57 reads (18%) | called by mutect2, varscan2
- COL12A1 | c.7950+35G>C | Intron (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2
- EIF3IP1 | n.382C>A | RNA (SNP) | VAF 31/178 reads (17%) | catalogued as rs61747657; called by muse, mutect2, varscan2
- FAM86DP | n.745C>T | RNA (SNP) | VAF 93/321 reads (29%) | catalogued as rs766076752; called by muse, varscan2
- FUS | c.-34C>T | 5'UTR (SNP) | VAF 246/807 reads (30%) | catalogued as rs765945796, COSV99568529, COSV99569043; called by muse, mutect2, varscan2
- GOLGA8J | c.591+159G>C | Intron (SNP) | VAF 132/565 reads (23%) | called by muse, mutect2, varscan2
- GUSBP10 | n.251C>T | RNA (SNP) | VAF 26/306 reads (8%) | catalogued as rs766815205; called by muse, mutect2
- GUSBP3 | chr5:69635795 C>T | 3'Flank (SNP) | VAF 90/202 reads (45%) | called by muse, mutect2, varscan2
- GVINP1 | n.4530A>T | RNA (SNP) | VAF 27/180 reads (15%) | called by muse, mutect2, varscan2
- LRR1 | chr14:49598666 G>A | 5'Flank (SNP) | VAF 141/621 reads (23%) | called by muse, mutect2, varscan2
- OR56B3P | n.678G>C | RNA (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- PENK | c.138+43G>C | Intron (SNP) | VAF 18/280 reads (6%) | catalogued as rs746975349; called by muse, mutect2
- PPM1A | chr14:60246018 G>A | 5'Flank (SNP) | VAF 7/38 reads (18%) | catalogued as rs753014508; called by muse, mutect2, varscan2
- SDHAP2 | n.974C>T | RNA (SNP) | VAF 76/1337 reads (6%) | catalogued as rs758787551; called by muse, mutect2
- SLC41A3 | c.274-5395C>G | Intron (SNP) | VAF 50/264 reads (19%) | catalogued as COSV100259753; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 61/228 reads (27%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- UGDH | c.-8+169G>A | Intron (SNP) | VAF 27/235 reads (11%) | called by muse, mutect2, varscan2
- ZNF451 | c.186+2713G>C | Intron (SNP) | VAF 43/214 reads (20%) | called by muse, mutect2, varscan2
- ZNF638 | c.-323C>G | 5'UTR (SNP) | VAF 54/176 reads (31%) | catalogued as rs1020097188; called by muse, mutect2, varscan2
